Somatic mutation profile of tumor specimen TARGET-30-PATPXJ-01A (aliquot TARGET-30-PATPXJ-01A-01D) from TARGET case TARGET-30-PATPXJ, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Overlapping lesion of retroperitoneum and peritoneum; Age at diagnosis: 3.1 years (1,125 days).
Specimen TARGET-30-PATPXJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 224cf34c-c2ea-44a3-a400-6cfe07a729bf.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATPXJ-10A (Blood Derived Normal), aliquot TARGET-30-PATPXJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2371ee89-7061-4ed9-be8e-c11b3b96bf7e

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NLRP3 | c.416G>T p.R139I | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV60223252; called by muse, mutect2, varscan2
- ANKRD30A | c.3447C>A p.T1149= (on ENST00000611781; = p.T1093= on NM_052997.2) | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as COSV64608971, COSV64621245; called by muse, mutect2, varscan2
- LIN28A | c.*1535C>A | 3'UTR (SNP) | VAF 20/308 reads (6%) | called by muse, mutect2
